MMRF case MMRF_2068 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3e5df490-87dc-4968-b55d-aed8a396f3bd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Dead; Days to death: 654 days (1.8 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.8 years (30,225 days); ISS stage: III; Days to last known disease status: 654 days (1.8 years); Days to last follow up: 654 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 397 days (1.1 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 391 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 654.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.725 mg/dL; Immunoglobulin G 2.27 g/L; Immunoglobulin A 28.1 g/L; Immunoglobulin M 0.181 g/L; Beta 2 Microglobulin 5.82 µg/mL; Lactate Dehydrogenase 4.37 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 8.92 ×10⁹/L; Absolute Neutrophil 8.42 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 71.6 µmol/L; Calcium 2.1 mmol/L; Albumin 28 g/L; Total Protein 6.5 g/dL; Glucose 6.82 mmol/L; C-Reactive Protein 0.31 mg/dL.
- Day 91 (ECOG 2): M Protein 0 g/dL; Immunoglobulin G 2.3 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.229 g/L; Beta 2 Microglobulin 8.47 µg/mL; Lactate Dehydrogenase 5.8 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 6.56 ×10⁹/L; Absolute Neutrophil 5.71 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 111 µmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 7.04 mmol/L.
- Day 180 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.659 mg/dL; Immunoglobulin G 3.64 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.364 g/L; Lactate Dehydrogenase 6.85 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 8.45 ×10⁹/L; Absolute Neutrophil 6.42 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 103 µmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 6.27 mmol/L.
- Day 285 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.856 mg/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 0.421 g/L; Immunoglobulin M 0.512 g/L; Beta 2 Microglobulin 5.28 µg/mL; Lactate Dehydrogenase 6.85 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8.13 ×10⁹/L; Absolute Neutrophil 6.11 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 5.8 g/dL; Glucose 5.23 mmol/L.
- Day 369 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 4.5 g/L; Immunoglobulin A 0.767 g/L; Immunoglobulin M 0.299 g/L; Beta 2 Microglobulin 7.04 µg/mL; Lactate Dehydrogenase 6.6 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 9.12 ×10⁹/L; Absolute Neutrophil 6.52 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 84 µmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 6.44 mmol/L.
- Day 448 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 4.31 g/L; Immunoglobulin A 0.697 g/L; Immunoglobulin M 0.315 g/L; Beta 2 Microglobulin 8.85 µg/mL; Lactate Dehydrogenase 4.75 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 8.68 ×10⁹/L; Absolute Neutrophil 5.75 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 145 µmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 6.22 mmol/L.
- Day 532 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.95 mg/dL; Immunoglobulin G 6.1 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 1.2 g/L; Lactate Dehydrogenase 6.72 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 9.14 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 103 µmol/L; Calcium 2.02 mmol/L; Albumin 32.9 g/L; Total Protein 5.3 g/dL; Glucose 4.46 mmol/L.
- Day 623 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.01 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 1.67 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 13.5 ×10⁹/L; Absolute Neutrophil 10.9 ×10⁹/L; Platelets 209 ×10⁹/L.

Other clinical attributes
- Day 1: Weight: 63 kg; Height: 150 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2068_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2068_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
